Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5K5, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5K5-01A (Primary Tumor).

[page 1 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: F
ADM DATE:

BIRTHDATE:

PAT TYPE:

ICD O-3
Carcinoma, adrenal cortical
8370/3
Site: (C) Adrenal Gland, cortex
Q74.0
9/30/13

OPER DATE:

PROCEDURE: SPHS

Patient with left adrenal mass.

PROCEDURE: SPGD

1. "L adrenal mass" Received fresh for frozen section is a fully-encapsulated, 447 gram, excision specimen (up to 14.5 cm x up to 9.5 cm x up to 6 cm). Inked green on its entire exterior capsule and bivalved to reveal an interior, mottled red-brown and orange, with areas highly suspicious for necrosis. Sampled for frozen section analysis and extensively for tissue procurement. Extensively sectioned to reveal scant extratumoral adipose, no attached lymph nodes, and no identifiable uninvolved adrenal tissue. Gross estimation of necrotic tumor mass approximately 30%.
- 1A. Frozen section control.
- 1B-C. Large central sections of lesion.
- 1D-K. Additional sections showing full range of gross morphology of the lesion and sampling margins from which it is grossly free. greater than one section per cm of tumor).
2. "Left periaortic lymph node packet" Received in formalin in a small container is a lymphadenectomy specimen (4 x 3 x 2 cm). Serially sectioned to reveal multiple small lymph node candidates.
- 2A-D. / candidates, small amount of adipose tissue)
3. "Left suprarenal periaortic lymph nodes" Received in formalin in a small container is a lymphadenectomy specimen (2 x 2 x 0.6 cm). Dissected, the specimen appears to consist predominantly of vascular tissue. Submitted entirely in cassette 3A.

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: F
ADM DATE:

BIRTHDATE:

OPER DATE:

FROZEN SECTION REPORT

1. Positive for carcinoma

Frozen section diagnosis is confirmed.

PROCEDURE: SPMI

ADRENOCORTICAL CARCINOMA
=====

Tumor Size: 14.5 x 9.5 x 6 cm
Tumor Weight: 447 grams
Capsular Invasion: Yes
Vascular Invasion: Yes
Surgical Margins: Negative but close
Necrosis: Yes
Mitotic Rate: 31 mitoses / 50 high power fields
Grade: High
Lymph nodes status: Negative (0/20).
Extra-adrenal extension: Yes, focal
Stage: III (extra-adrenal extension)
Immunohistochemistry Results: NA

PROCEDURE: SPDX

1. Left adrenal gland, resection: Adrenocortical carcinoma, high-grade by mitotic rate, margins negative but close. See Template.

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

BIRTHDATE:

PAGE #: 4
SEX: F
ADM DATE:

OPER DATE:

2. Lymph node, left periaortic, excision: Twenty lymph nodes negative for carcinoma (0/20).

3. Soft tissue, left suprarenal, excision: Ganglion and fibrovascular tissue, negative for carcinoma.

., the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Dual/Synchronous Pathology Ordered		☒

Source: NCI Genomic Data Commons file 922a51c5-2f6f-4284-a566-9d3d929c759a (TCGA-OR-A5K5.6EA3FB77-3DD4-43C8-8C39-CA8755EBC50C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).